Somatic mutation profile of tumor specimen TCGA-ZG-A9KY-01A (aliquot TCGA-ZG-A9KY-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9KY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 73.9 years (27,000 days).
Specimen TCGA-ZG-A9KY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 501da76a-147c-4c68-b166-f55e78e2ccc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9KY-10A (Blood Derived Normal), aliquot TCGA-ZG-A9KY-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b71864bd-66dd-49e1-b963-aede10f6bbae

The open-access MAF lists 69 somatic variants for this specimen: 50 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 17, Frame Shift Del 5, Frame Shift Ins 5, Nonsense Mutation 2, Splice Region 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 39/50 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as COSV100651449; called by muse, mutect2, varscan2
- ANKAR | c.570_573del p.N190Kfs*12 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs754752428; called by mutect2, pindel, varscan2
- ATR | c.2497G>T p.E833* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100638644, COSV63392006; called by muse, mutect2, varscan2
- BSN | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV99610133; called by muse, mutect2, varscan2
- CACNG7 | c.764C>T p.T255M | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1445416001, COSV55813899; called by muse, mutect2, varscan2
- CCDC136 | c.1355G>A p.C452Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV99923395; called by muse, mutect2, varscan2
- CDK12 | c.2086C>T p.Q696* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV101420582; called by muse, mutect2, varscan2
- DDRGK1 | c.560A>C p.E187A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100621555; called by muse, mutect2, varscan2
- DOCK11 | c.5132G>A p.R1711H | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201193128, COSV99355012; called by muse, mutect2, varscan2
- DOCK6 | c.4480G>A p.E1494K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs568049240, CM148863, COSV99626959; called by muse, mutect2, varscan2
- DPEP2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs748950745, COSV99263260; called by muse, mutect2, varscan2
- DRD5 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs77784509; called by muse, mutect2, varscan2
- ELAPOR2 | c.2347G>T p.D783Y (on ENST00000450689 / NM_001142749.3; = p.D616Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51891938, COSV99789513; called by muse, mutect2, varscan2
- FPR1 | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866198922, COSV59052992; called by muse, mutect2, varscan2
- GJB5 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs148092547, COSV58355409; called by muse, mutect2, varscan2
- HACD1 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 6/61 reads (10%) | catalogued as COSV100778521; called by muse, mutect2, varscan2
- HSPA8 | c.364A>G p.M122V | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.065); catalogued as COSV99914694; called by muse, mutect2, varscan2
- HTT | c.2414C>T p.A805V | Missense Mutation (SNP) | VAF 75/172 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs140979048, COSV61865852; called by muse, mutect2, varscan2
- LYST | c.10812A>G p.I3604M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV101090478; called by muse, mutect2, varscan2
- MAP1A | c.7435C>T p.R2479W | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs766441031, COSV55811917; called by muse, mutect2, varscan2
- METTL9 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100820664; called by muse, mutect2, varscan2
- NBL1 | c.-18G>A | Splice Region (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99229702; called by muse, mutect2, varscan2
- NR1D1 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs576443916, COSV99225855; called by muse, mutect2, varscan2
- OR52J3 | c.452T>C p.V151A | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV66747865; called by muse, mutect2, varscan2
- PI4KA | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV55412034; called by muse, mutect2, varscan2
- PLRG1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100123300; called by muse, mutect2, varscan2
- RAB8B | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100369103; called by muse, mutect2
- RASL10A | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.94); catalogued as COSV99329762; called by muse, mutect2, varscan2
- SATB2 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.041); catalogued as rs372032415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIK3 | c.482G>C p.R161P (on ENST00000445177 / NM_001366686.2; = p.R167P on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV99408999; called by muse, mutect2, varscan2
- SMARCAD1 | c.2303dup p.N768Kfs*28 | Frame Shift Ins (INS) | VAF 15/44 reads (34%) | catalogued as rs750056186; called by mutect2, varscan2
- SNTG1 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.758); catalogued as COSV99386788; called by muse, mutect2, varscan2
- SOX5 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58628809, COSV58652994; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1741G>A p.D581N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | PolyPhen possibly damaging (0.483); catalogued as rs746641827, COSV50073490; called by muse, mutect2, varscan2
- SZT2 | c.8593C>T p.P2865S (on ENST00000634258 / NM_001365999.1; = p.P2808S on NM_015284.4) | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs146439294; called by muse, mutect2, varscan2
- TAP1 | c.1888C>A p.P630T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as COSV100841343; called by muse, mutect2, varscan2
- UBQLN4 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV64149925; called by muse, mutect2, varscan2
- VILL | c.2036G>C p.G679A | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as COSV99379362; called by muse, mutect2, varscan2
- ZFP57 | c.1168T>C p.S390P | Missense Mutation (SNP) | VAF 99/283 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100971999; called by muse, mutect2, varscan2
- ZNF502 | c.844C>T p.L282F | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs763118807, COSV99939901; called by muse, mutect2, varscan2
- ZNF777 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs770757126, COSV99924976; called by muse, mutect2, varscan2
- CDK12 | c.1772dup p.T592Dfs*49 | Frame Shift Ins (INS) | VAF 51/176 reads (29%) | called by mutect2, pindel, varscan2
- IRF6 | c.1010_1017del p.I337Tfs*14 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- KDM4B | c.308dup p.N103Kfs*14 | Frame Shift Ins (INS) | VAF 10/52 reads (19%) | called by mutect2, pindel
- KMT2C | c.7221del p.S2408Hfs*44 | Frame Shift Del (DEL) | VAF 47/275 reads (17%) | called by mutect2, pindel, varscan2
- PIGG | c.177_184dup p.P62Rfs*14 | Frame Shift Ins (INS) | VAF 16/77 reads (21%) | called by mutect2, varscan2
- SHROOM4 | c.3941dup p.I1315Dfs*47 | Frame Shift Ins (INS) | VAF 28/48 reads (58%) | called by mutect2, varscan2
- SUPT20HL2 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- VPS50 | c.2187_2188del p.R729Sfs*12 | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | called by pindel, varscan2
- WASF2 | c.443_444del p.K148Ifs*10 | Frame Shift Del (DEL) | VAF 17/110 reads (15%) | called by mutect2, pindel, varscan2
- ADGRA3 | c.3612C>T p.N1204= | Silent (SNP) | VAF 65/157 reads (41%) | catalogued as rs146569496; called by muse, mutect2, varscan2
- CACNA1E | c.1155C>T p.A385= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100705834; called by muse, mutect2, varscan2
- CC2D2A | c.3021G>A p.L1007= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1342872302, COSV101052993; called by muse, mutect2, varscan2
- CEACAM7 | c.585C>T p.S195= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV99137496; called by muse, mutect2, varscan2
- CERK | c.1503C>T p.C501= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs375210247; called by muse, mutect2
- CPT1C | c.1761G>A p.E587= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV99773752; called by muse, mutect2, varscan2
- EPO | c.342G>A p.P114= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs768971818, COSV99402691; called by muse, mutect2, varscan2
- GAK | c.930G>A p.V310= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as rs762174389, COSV100034192; called by muse, mutect2, varscan2
- KDM4B | c.330G>A p.P110= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV50283936; called by muse, mutect2, varscan2
- PIGG | c.1542G>C p.L514= (on ENST00000453061 / NM_001127178.3; = p.L506= on NM_017733.4) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99574509; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1902C>T p.C634= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs370291693, COSV99461953; called by muse, mutect2, varscan2
- PPP2R5C | c.1458G>A p.P486= | Silent (SNP) | VAF 35/184 reads (19%) | catalogued as rs891751251, COSV100160234; called by muse, mutect2, varscan2
- RUFY4 | c.1215G>A p.E405= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs1181109694, COSV100723252; called by muse, mutect2, varscan2
- SHARPIN | c.813C>T p.V271= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as COSV59644342, COSV59644921; called by muse, mutect2, varscan2
- SLX4IP | c.540G>A p.T180= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs375752597; called by muse, mutect2, varscan2
- XAGE2 | c.180G>A p.E60= | Silent (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- ZNF492 | c.504C>A p.P168= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV101514076; called by muse, mutect2, varscan2
- DCHS2 | n.4994G>A | RNA (SNP) | VAF 9/44 reads (20%) | catalogued as COSV61772333; called by muse, mutect2, varscan2
- DLGAP1 | c.1592-14971G>A | Intron (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100234570; called by muse, mutect2, varscan2
